Surgical pathology report (de-identified scan), TCGA case TCGA-10-0925, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-10-0925-01A (Primary Tumor).

[page 1 of 2]
* TSSI Unique Patient # [REDACTED]

** Case imported from legacy / [REDACTED] outer system. The format of this report [REDACTED] s not match the original case. **

DIAGNOSIS

- (A) OMENTUM:
METASTATIC PAPILLARY SEROUS CARCINOMA, LOW GRADE.
- (B) RIGHT TUBE AND OVARY:
SEROUS BORDERLINE NEOPLASM WITH MULTIPLE FOCI OF MICROINVASION AND A FOCUS OF LOW GRADE SEROUS CARCINOMA.
- (C) LEFT TUBE AND OVARY:
LOW GRADE SEROUS CARCINOMA IN A BACKGROUND OF SEROUS BORDERLINE NEOPLASM.
- (D) TUMOR BLADDER PERITONEUM:
METASTATIC LOW GRADE PAPILLARY SEROUS CARCINOMA.
- (E) UTERUS AND CERVIX:
Endometrial polyp.
METASTATIC LOW GRADE SEROUS CARCINOMA IN UTERINE SEROSA.
- (F) LEFT PELVIC SIDEWALL TUMOR:
METASTATIC LOW GRADE PAPILLARY SEROUS CARCINOMA.
- (G) RIGHT PELVIC LYMPH NODE:
METASTATIC LOW GRADE PAPILLARY SEROUS CARCINOMA IN ONE OF SEVEN LYMPH NODES.
- (H) LEFT PELVIC LYMPH NODE:
Four lymph nodes, no tumor seen.

[REDACTED]

Entire report and diagnosis completed by: [REDACTED]

Report released by: [REDACTED]

GROSS DESCRIPTION

(A) OMENTUM - A tan-pink tumor nodule (24.0 x 11.0 x 1.5 cm). There are multiple fleshy tan-pink tumor nodules involving the omentum, the largest measuring 2.5 x 1.8 x 1.5 cm. There are multiple other tumor nodules ranging from 0.3 to 1.6 cm in greatest dimensions.

SECTION CODE: A1, tumor for FS; A2-A11, omental tumor nodules. [REDACTED]

(B) RIGHT TUBE AND OVARY - Consists of an enlarged ovary (15.0 x 10.0 x 10.0 cm). The fallopian tube (5.0 x 0.6 x 0.5 cm). the ovary has cystic and solid areas. The cystic areas contain yellow serous fluid and the solid areas contain fleshy tan-pink tumor. In areas, the wall of the cyst is glistening, tan-pink, and smooth. Other areas show fine tan-pink granularity. Several areas of pale yellow tumor necrosis are identified. The larger nodules of solid tumor measure up to 6.0 cm. One area of tumor necrosis measures 2.5 cm in greatest dimension. The fallopian tube has a tan-pink glistening serosal surface. There is focal small tan-pink nodules in the paratubal soft tissue (0.4 x 0.3 x 0.2 cm). Several fleshy pink tumor implants are seen on the surface of the ovary. These range from 0.5 up to 2.3 cm in greatest dimension.

SECTION CODE: B1-B5, ovarian tumor for FS; B6-B11, ovarian surface tumor implant; B12-B20, ovarian tumor with cyst wall; B21, fallopian tube with paratubal nodule. [REDACTED]

(C) LEFT TUBE AND OVARY - This is a large cystic ovary (11.0 x 9.0 x 5.5 cm) and attached fallopian tube (5.0 x 0.6 x 0.5 cm). The ovary is predominantly

[page 2 of 2]
TSSI Unique Patient

cystic containing a clear yellow serous fluid. The cyst wall for the most part is smooth with nodularity and granularity (0.1 and up large areas of papillary surface tan-pink color). The largest area measures 2.5 x 2.0 x 1.5 cm. Numerous surface tumor implants are present ranging from 0.3 up to 3.5 cm in greatest dimensions.

SECTION CODE: C1-C5, left ovary tumor with tumor implant; C6-C9, left ovary tumor with cyst.

(D) TUMOR BLADDER PERITONEUM - This is an oval tan-pink tumor nodule (2.5 x 1.8 x 1.0 cm).

SECTION CODE: D1, D2, tumor nodule.

(E) UTERUS AND CERVIX - This is a small uterus and cervix (7.3 x 4.5 x 1.9 cm). The cervical os is tan-pink with focal punctate hemorrhage. The serosa has prominent surface adhesions and the endocervical canal and endometrium are tan-pink. Focally, there is a small endometrial polyp at the fundus (1.2 x 1.0 x 0.2 cm). The myometrium measures 1.0 cm in thickness. Focally, there is a circumscribed anterior endometrial nodule (0.8 x 0.5 x 0.3 cm). Also, on the posterior serosal surface section through one of the area of adhesion suspicious for tan-pink tumor and 1.2 cm in greatest dimension.

SECTION CODE: E1, anterior cervix; E2, posterior cervix; E3, anterior endomyometrium; E4, posterior endomyometrium; E5, endometrial polyp; E6, myometrial nodule and posterior uterine serosa; E7, posterior uterine serosa.

(F) LEFT PELVIC SIDEWALL TUMOR - This is an irregular hemorrhagic red fragment of peritoneal surface with focal firm nodularity (1.0 x 1.0 x 0.3 cm).

(G) RIGHT PELVIC LYMPH NODE - This is yellow fatty tissue (5.0 x 3.0 x 1.0 cm). Five tan lymph nodes are identified ranging from 0.3 to 1.1 cm in greatest dimension.

SECTION CODE: G1, one lymph node; G2, two lymph nodes; G3-G4, several lymph nodes (G3 one lymph node, G4 two suspected lymph nodes).

(H) LEFT PELVIC LYMPH NODE - This is an oval portion of yellow fat (3.5 x 2.5 x 0.8 cm). Six tan suspected lymph nodes are identified ranging from 0.3 to 0.9 cm in greatest dimension.

SECTION CODE: H1, multiple lymph nodes; H2, one lymph node; H3, two lymph nodes.

-----END OF REPORT-----

Source: NCI Genomic Data Commons file 36e45c9e-74fa-4188-b667-4cf500f8d89c (TCGA-10-0925.96F0F453-84F9-401A-9FD0-0A8712A87BE5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).